Somatic mutation profile of tumor specimen TCGA-H6-8124-01A (aliquot TCGA-H6-8124-01A-11D-2396-08) from TCGA case TCGA-H6-8124, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 56.8 years (20,741 days).
Specimen TCGA-H6-8124-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84611461-b56b-4ba7-bca5-f34fb19d5b09.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-H6-8124-10A (Blood Derived Normal), aliquot TCGA-H6-8124-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ddb49c15-06d5-4137-8fed-8a6e51d84d90

The open-access MAF lists 39 somatic variants for this specimen: 31 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 26, Silent 8, In Frame Del 2, Splice Site 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 66/96 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 155/269 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ADAM22 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 94/428 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV99717194; called by muse, mutect2, varscan2
- ADD3 | c.479A>G p.Y160C | Missense Mutation (SNP) | VAF 134/240 reads (56%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs762913932, COSV53324127, COSV99523469; called by muse, mutect2, varscan2
- AJAP1 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs138033447; called by muse, mutect2, varscan2
- ARAF | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 80/195 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.07); catalogued as rs777037087, COSV51691699; called by muse, mutect2, varscan2
- ARHGEF17 | c.5869C>T p.R1957W | Missense Mutation (SNP) | VAF 103/335 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV99735792; called by muse, mutect2, varscan2
- CLCN5 | c.1606G>A p.V536M | Missense Mutation (SNP) | VAF 423/1181 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs782060809, COSV56584208; ClinVar: benign; called by muse, mutect2, varscan2
- CUX1 | c.3132A>C p.E1044D | Missense Mutation (SNP) | VAF 957/2886 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99471789; called by muse, mutect2, varscan2
- DEPDC1 | c.769+1G>T p.X257_splice | Splice Site (SNP) | VAF 134/440 reads (30%) | catalogued as COSV100920357; called by muse, varscan2
- DUSP6 | c.1024G>T p.D342Y | Missense Mutation (SNP) | VAF 299/544 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99684067; called by muse, mutect2, varscan2
- FCGBP | c.11191G>A p.E3731K | Missense Mutation (SNP) | VAF 120/228 reads (53%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.884); catalogued as rs771095205; called by muse, mutect2, varscan2
- FLNA | c.4150G>T p.G1384C | Missense Mutation (SNP) | VAF 593/1724 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100774783; called by muse, mutect2, varscan2
- GRID2 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 236/714 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.185); catalogued as rs1191837177, COSV99941706; called by muse, mutect2, varscan2
- HR | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 36/370 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as rs765212418, COSV100455854; ClinVar: uncertain significance; called by muse, mutect2
- IGSF8 | c.606T>G p.F202L | Missense Mutation (SNP) | VAF 207/659 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100081686; called by muse, mutect2, varscan2
- KLHDC8A | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 282/822 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.412); catalogued as rs768279570, COSV100903772; called by muse, mutect2, varscan2
- LRIF1 | c.910C>T p.L304F | Missense Mutation (SNP) | VAF 162/481 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100870855; called by muse, mutect2, varscan2
- MAP4K2 | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 117/364 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99581111; called by muse, mutect2, varscan2
- MYO9B | c.502C>A p.H168N | Missense Mutation (SNP) | VAF 352/696 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV101261612, COSV68282281; called by muse, mutect2, varscan2
- N4BP2L2 | c.580A>G p.K194E | Missense Mutation (SNP) | VAF 150/407 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV99912598; called by muse, mutect2, varscan2
- POM121L12 | c.608G>A p.S203N | Missense Mutation (SNP) | VAF 245/701 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.25); catalogued as rs768334548, COSV101374926; called by muse, mutect2, varscan2
- PRTFDC1 | c.640G>T p.V214F | Missense Mutation (SNP) | VAF 208/443 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100196965; called by muse, mutect2, varscan2
- PXDN | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as rs935054476, COSV99413766; called by muse, mutect2, varscan2
- TOPBP1 | c.4243C>T p.L1415F | Missense Mutation (SNP) | VAF 91/288 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1461551494, COSV99605410; called by muse, mutect2, varscan2
- ZFYVE28 | c.1577C>T p.S526F | Missense Mutation (SNP) | VAF 180/601 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.406); catalogued as rs988422580, COSV99343053; called by muse, mutect2, varscan2
- ZNF585A | c.313A>G p.N105D (on ENST00000292841 / NM_001288800.2; = p.N50D on NM_152655.3) | Missense Mutation (SNP) | VAF 668/1321 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as COSV99493224; called by muse, mutect2, varscan2
- ADCY1 | c.397_399del p.F133del | In Frame Del (DEL) | VAF 100/277 reads (36%) | called by mutect2, pindel, varscan2
- LRPAP1 | c.908_914del p.E303Gfs*13 | Frame Shift Del (DEL) | VAF 251/824 reads (30%) | called by mutect2, pindel, varscan2
- RAP2B | c.445_480del p.N149_I160del | In Frame Del (DEL) | VAF 44/157 reads (28%) | called by mutect2, pindel
- ZNF211 | c.1632dup p.S545Ifs*33 (on ENST00000347302 / NM_198855.4; = p.S558Ifs*33 on NM_006385.5) | Frame Shift Ins (INS) | VAF 620/1489 reads (42%) | called by mutect2, pindel, varscan2
- ARHGDIB | c.540C>T p.D180= | Silent (SNP) | VAF 612/847 reads (72%) | catalogued as rs776957092, COSV56764300; called by muse, mutect2, varscan2
- CELSR3 | c.930G>A p.A310= | Silent (SNP) | VAF 107/652 reads (16%) | catalogued as rs755065079, COSV50840047; called by muse, mutect2, varscan2
- DLL1 | c.567C>T p.S189= | Silent (SNP) | VAF 159/342 reads (46%) | catalogued as COSV100816099; called by muse, mutect2, varscan2
- IL12B | c.282C>T p.G94= | Silent (SNP) | VAF 125/362 reads (35%) | catalogued as rs142017503; called by muse, mutect2, varscan2
- MAML2 | c.2160C>T p.G720= | Silent (SNP) | VAF 149/418 reads (36%) | catalogued as rs367763533; called by muse, mutect2, varscan2
- PANK4 | c.1644G>A p.L548= | Silent (SNP) | VAF 376/1101 reads (34%) | catalogued as COSV101022452; called by muse, mutect2
- SOHLH2 | c.1068G>A p.A356= | Silent (SNP) | VAF 326/854 reads (38%) | catalogued as rs375286456, COSV65902818; called by muse, mutect2, varscan2
- XKR7 | c.867C>T p.D289= | Silent (SNP) | VAF 83/292 reads (28%) | catalogued as rs1303010032, COSV73813317; called by muse, mutect2, varscan2
